Somatic mutation profile of tumor specimen 0DK1W9 from CCDI case PBBWUG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Age at diagnosis: 4.3 years (1,563 days).
Specimen 0DK1W9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4df9cd10-982e-4be2-9186-ff4fff3bf7cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK1WG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/571ac3ab-3dc1-40d7-bdc5-e36f141704b1

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Frame Shift Ins 2, Intron 2, Splice Region 2, 5'UTR 1, Frame Shift Del 1, RNA 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 372/1024 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- AMER3 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 289/891 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs949105785, COSV58465006; called by muse, mutect2, varscan2
- ESR1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 391/911 reads (43%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.818); catalogued as rs373558014; called by muse, mutect2, varscan2
- IGDCC4 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 294/569 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs576203297; called by muse, mutect2, varscan2
- LRRC70 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 106/897 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774910601, COSV100320796; called by muse, mutect2, varscan2
- MUC5AC | c.16900G>A p.E5634K | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as rs368705249; called by muse, mutect2, varscan2
- NCAPH | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 475/1327 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.287); catalogued as rs139431721; called by muse, mutect2, varscan2
- NEU4 | c.124C>A p.Q42K (on ENST00000391969 / NM_001167602.3; = p.Q54K on NM_080741.4) | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.055); catalogued as rs1335229368; called by muse, mutect2
- NIM1K | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 67/516 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV58141127; called by muse, mutect2, varscan2
- PDE3A | c.511dup p.E171Gfs*49 | Frame Shift Ins (INS) | VAF 226/578 reads (39%) | catalogued as rs780389664; called by mutect2, varscan2
- PPWD1 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 155/635 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs142815878; called by muse, mutect2, varscan2
- RAB40AL | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 100/493 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505105; called by muse, mutect2, varscan2
- SGTA | c.636C>T p.P212= | Splice Region (SNP) | VAF 268/978 reads (27%) | catalogued as rs147715180; called by muse, mutect2, varscan2
- SIPA1L3 | c.4442C>T p.T1481M | Missense Mutation (SNP) | VAF 152/721 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs147521492; called by muse, varscan2
- SPTLC3 | c.1152G>A p.K384= | Splice Region (SNP) | VAF 310/1226 reads (25%) | catalogued as rs1027507899, COSV65465996; called by muse, mutect2, varscan2
- UBE2Z | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 495/1195 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs144649420; called by muse, mutect2, varscan2
- ZNF407 | c.5830G>A p.V1944M | Missense Mutation (SNP) | VAF 176/487 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1027928506; called by muse, mutect2, varscan2
- ZNF853 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 216/2320 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as rs935984370, COSV71922844; called by muse, mutect2
- ABCA9 | c.2267C>A p.T756K | Missense Mutation (SNP) | VAF 114/671 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by mutect2, varscan2
- BACE2 | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 206/1149 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 38/1556 reads (2%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CLINT1 | c.1372A>G p.R458G | Missense Mutation (SNP) | VAF 160/521 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTR9 | c.1414-1G>T p.X472_splice | Splice Site (SNP) | VAF 240/531 reads (45%) | called by mutect2, varscan2
- DOCK11 | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 173/721 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGFR4 | c.1716_1725dup p.G576Qfs*9 | Frame Shift Ins (INS) | VAF 118/455 reads (26%) | called by mutect2, varscan2
- GDF3 | c.629G>T p.R210I | Missense Mutation (SNP) | VAF 188/442 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.178); called by mutect2, varscan2
- MED1 | c.438T>A p.N146K | Missense Mutation (SNP) | VAF 98/874 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- POM121L2 | c.2410T>A p.S804T | Missense Mutation (SNP) | VAF 37/817 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2
- RGPD4 | c.2876G>C p.R959P | Missense Mutation (SNP) | VAF 106/944 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.145); called by muse, mutect2
- RSC1A1 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 220/1358 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SDR16C5 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 246/1902 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHROOM3 | c.2075G>T p.R692M | Missense Mutation (SNP) | VAF 20/575 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2
- THTPA | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 312/720 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TMEM117 | c.1490G>C p.S497T | Missense Mutation (SNP) | VAF 401/929 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- VGLL2 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 96/461 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ZFP36L2 | c.659_663del p.E220Afs*252 | Frame Shift Del (DEL) | VAF 201/587 reads (34%) | called by mutect2, pindel, varscan2
- ZNF461 | c.1348T>C p.F450L | Missense Mutation (SNP) | VAF 95/356 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADARB2 | c.1626C>T p.D542= | Silent (SNP) | VAF 101/392 reads (26%) | catalogued as rs749348675, COSV67224537; called by muse, mutect2, varscan2
- DZIP1L | c.258G>C p.V86= | Silent (SNP) | VAF 104/583 reads (18%) | called by muse, mutect2, varscan2
- LRRC25 | c.670C>A p.R224= | Silent (SNP) | VAF 187/802 reads (23%) | called by muse, mutect2, varscan2
- MAP3K1 | c.135G>A p.R45= | Silent (SNP) | VAF 186/329 reads (57%) | called by muse, mutect2, varscan2
- MUC22 | c.2118C>T p.T706= | Silent (SNP) | VAF 109/751 reads (15%) | called by muse, mutect2, varscan2
- PREP | c.483G>A p.E161= (on ENST00000369110; = p.E227= on NM_002726.5) | Silent (SNP) | VAF 171/959 reads (18%) | called by muse, mutect2, varscan2
- SPAG16 | c.687G>T p.V229= | Silent (SNP) | VAF 326/1135 reads (29%) | called by muse, mutect2, varscan2
- ZNF440 | c.1680C>T p.Y560= | Silent (SNP) | VAF 160/1919 reads (8%) | catalogued as rs766528860, COSV58371015; called by muse, mutect2
- CDC40 | chr6:110180393 G>A | 5'Flank (SNP) | VAF 155/328 reads (47%) | catalogued as rs1165449296; called by muse, mutect2, varscan2
- CRIP1 | c.136-29G>C | Intron (SNP) | VAF 29/416 reads (7%) | called by muse, mutect2
- HBE1 | c.-267+102817G>T | Intron (SNP) | VAF 247/558 reads (44%) | called by muse, mutect2, varscan2
- SLC66A1 | c.-19G>T | 5'UTR (SNP) | VAF 247/482 reads (51%) | catalogued as rs868535629, COSV100913337; called by muse, mutect2, varscan2
- SLC66A1L | n.212C>T | RNA (SNP) | VAF 213/881 reads (24%) | called by muse, mutect2, varscan2
